Somatic mutation profile of tumor specimen TARGET-40-NAAWGG-01A (aliquot TARGET-40-NAAWGG-01A-01D) from TARGET case TARGET-40-NAAWGG, project TARGET-OS (Osteosarcoma). Sex at birth: female; Primary diagnosis: Osteosarcoma, NOS; Age at diagnosis: 12.0 years (4,380 days).
Specimen TARGET-40-NAAWGG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df3c5b4f-0d3b-4361-b1b3-5918f8f51038.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAWGG-10A (Blood Derived Normal), aliquot TARGET-40-NAAWGG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8442db9-d5e5-4b6e-a4b0-7b9ea7862979

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH18 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 159/318 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776963132, COSV56899350; called by muse, varscan2
- DGKG | c.2303C>T p.A768V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs558355832, COSV53961879, COSV99402248; called by muse, mutect2, varscan2
- KIF21A | c.3802G>A p.A1268T (on ENST00000361418 / NM_001378440.1; = p.A1255T on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100735555; called by muse, mutect2, varscan2
- ADGRF5 | c.597C>T p.T199= | Silent (SNP) | VAF 22/231 reads (10%) | catalogued as rs779173197; called by muse, mutect2
